TCGA case TCGA-24-1558 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba68f2cf-9271-41fd-9655-1fac7681f588

Demographics
Sex at birth: female; Race: white; Age at index: 73 years; Vital status: Dead; Days to death: 594 days (1.6 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 73.9 years (27,004 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 247 days; Number of cycles: 10; Treatment dose: 44 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 247 days; Number of cycles: 10; Treatment dose: 1,800 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 247 days; Number of cycles: 10; Treatment dose: 14 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Persistent Disease; Days to treatment start: 316 days; Days to treatment end: 382 days (1.0 years); Number of cycles: 4; Treatment dose: 524 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Persistent Disease; Days to treatment start: 316 days; Days to treatment end: 382 days (1.0 years); Number of cycles: 4; Treatment dose: 3,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 403 days (1.1 years); Days to treatment end: 487 days (1.3 years); Number of cycles: 4; Treatment dose: 277 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 515 days (1.4 years); Days to treatment end: 588 days (1.6 years); Number of cycles: 4; Treatment dose: 11,810 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 74.7 years (27,277 days); Days to diagnosis: 273 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 273 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 273 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 594 days (1.6 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1558-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.9; Intermediate dimension: 1; Shortest dimension: 0.9.
  Slide TCGA-24-1558-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 2.
  Slide TCGA-24-1558-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 2.
- Sample TCGA-24-1558-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Persistent disease treament.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 4: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Persistent disease treatment.
- Drug treatment 6: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 7: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 594 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 594 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 273 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-24-1558-01): tumor purity 0.91, ploidy 3.26, whole-genome doublings 1 (call status: legacy_call).
